Gene-level copy-number profile of tumor specimen TCGA-FE-A239-01A from TCGA case TCGA-FE-A239, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 82.8 years (30,259 days).
Specimen TCGA-FE-A239-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.88eb0586-4643-4677-845e-12051ee28a15.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FE-A239-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/d63eba99-1f95-4ecf-952c-c90d94646e7f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,688; copy number 2: 41,894; copy number 3: 7,470; copy number 4: 1,763; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:4,304,942–4,583,871, 5 genes, copy number 5 (within-gene range 3–5): AL162718.1, AL159166.1, AL162718.3, RNA5SP202, AL162718.2.

Autosomal genes at a single copy (total copy number 1): 6,267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
